Somatic mutation profile of cancer-model specimen HCM-BROD-0960-C16-85A (3D Organoid, passage 8; aliquot HCM-BROD-0960-C16-85A-01D-A87L-36), derived from the metastatic tumor of HCMI case HCM-BROD-0960-C16, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Age at diagnosis: 64.5 years (23,555 days).
Specimen HCM-BROD-0960-C16-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49325880-e6a9-4939-9c47-91b45a0d751b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0960-C16-10A (Blood Derived Normal), aliquot HCM-BROD-0960-C16-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b317b949-850e-4128-9af1-2660c1efb1dd

The open-access MAF lists 201 somatic variants for this specimen: 155 protein-altering or splice-affecting, 39 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 137, Silent 39, Nonsense Mutation 8, Frame Shift Del 5, Intron 5, Splice Region 2, Splice Site 2, 5'UTR 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNH5 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 206/412 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587777164, CM1310653, COSV59758318, COSV59758899; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- LDLR | c.681C>G p.D227E | Missense Mutation (SNP) | VAF 93/200 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908028, CD100947, CM068793, CM890080, COSV52944120; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1835A>G p.N612S | Missense Mutation (SNP) | VAF 173/372 reads (47%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.804); catalogued as rs764724028; called by muse, mutect2, varscan2
- ACTR8 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1452684482, COSV51635281; called by muse, mutect2, varscan2
- ADCY8 | c.1822T>C p.S608P | Missense Mutation (SNP) | VAF 511/1081 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs368131389; called by muse, mutect2, varscan2
- BEST3 | c.1382C>T p.T461M | Missense Mutation (SNP) | VAF 249/556 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs750674581, COSV58302493; called by muse, mutect2, varscan2
- BHMT | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 271/481 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.44); catalogued as COSV57153503; called by muse, mutect2, varscan2
- BICDL1 | c.715T>C p.S239P | Missense Mutation (SNP) | VAF 220/418 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.755); catalogued as rs773662348; called by muse, mutect2, varscan2
- C1QTNF9 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 177/672 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs780428044; called by muse, mutect2, varscan2
- CACNA1I | c.5416G>A p.V1806I | Missense Mutation (SNP) | VAF 191/403 reads (47%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.979); catalogued as rs370609693; called by muse, mutect2, varscan2
- CD109 | c.1513C>T p.Q505* | Nonsense Mutation (SNP) | VAF 33/101 reads (33%) | catalogued as rs756107413; called by muse, mutect2, varscan2
- CEP170 | c.2339C>G p.T780S | Missense Mutation (SNP) | VAF 64/525 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770527711, COSV60509032; called by muse, mutect2
- CEP68 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 282/283 reads (100%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs777440099; called by muse, mutect2, varscan2
- CGN | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 644/956 reads (67%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs768433517; called by muse, mutect2, varscan2
- COL3A1 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 246/514 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779625, CM119018, COSV100483591; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CPEB4 | c.2011C>T p.Q671* | Nonsense Mutation (SNP) | VAF 248/570 reads (44%) | catalogued as COSV99436928; called by muse, mutect2, varscan2
- FSIP2 | c.631A>G p.I211V | Missense Mutation (SNP) | VAF 89/198 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs997432494; called by muse, mutect2, varscan2
- FURIN | c.1001C>T p.S334L | Missense Mutation (SNP) | VAF 259/602 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1371698971, COSV99184619; called by muse, mutect2, varscan2
- GIPC3 | c.884G>A p.R295H (on ENST00000644946; = p.A291T on NM_133261.3) | Missense Mutation (SNP) | VAF 308/688 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as rs199951984; ClinVar: likely benign; called by muse, mutect2, varscan2
- HOXA2 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 195/397 reads (49%) | catalogued as COSV56066750; called by muse, mutect2, varscan2
- KLRK1 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV53698120; called by muse, mutect2, varscan2
- MCM6 | c.1342G>C p.A448P | Missense Mutation (SNP) | VAF 175/384 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51469564; called by muse, mutect2, varscan2
- NCAM2 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 181/403 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs573485921; called by muse, mutect2, varscan2
- OCSTAMP | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 140/426 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1003265035, COSV54096647; called by muse, mutect2, varscan2
- PHACTR3 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 213/707 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV63025184; called by muse, mutect2, varscan2
- PLCB4 | c.575C>G p.P192R | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1244478803, COSV53793656; called by muse, mutect2, varscan2
- PLEC | c.1499C>A p.P500Q (on ENST00000322810 / NM_201380.4; = p.P390Q on NM_000445.5) | Missense Mutation (SNP) | VAF 252/1043 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59687433; called by muse, mutect2, varscan2
- PLEKHG4 | c.210C>G p.F70L | Missense Mutation (SNP) | VAF 233/467 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV64613161; called by muse, mutect2, varscan2
- POLN | c.2267G>A p.R756Q | Missense Mutation (SNP) | VAF 198/421 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs193920976, COSV67024190; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPHLN1 | c.374G>T p.R125M | Missense Mutation (SNP) | VAF 158/351 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56737779; called by muse, mutect2, varscan2
- PTPRT | c.1958G>A p.R653Q | Missense Mutation (SNP) | VAF 209/677 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs724159842, COSV61985408, COSV61985479, COSV62019583; called by muse, mutect2, varscan2
- RIPK1 | c.764A>T p.Y255F | Missense Mutation (SNP) | VAF 250/502 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs567232503; called by muse, mutect2, varscan2
- ROBO2 | c.4063C>T p.R1355C | Missense Mutation (SNP) | VAF 186/386 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs554936963, COSV59901001, COSV59948476; called by muse, mutect2, varscan2
- ROGDI | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 182/353 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs566665742, COSV59021973; called by muse, mutect2, varscan2
- RTN4RL2 | c.369G>C p.E123D | Missense Mutation (SNP) | VAF 280/558 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV100625432; called by muse, mutect2, varscan2
- SCGN | c.153T>C p.D51= | Splice Region (SNP) | VAF 100/181 reads (55%) | catalogued as rs746274904; called by muse, mutect2, varscan2
- SGF29 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 202/435 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.323); catalogued as rs760551737; called by muse, mutect2
- SH3RF2 | c.922C>G p.L308V | Missense Mutation (SNP) | VAF 254/525 reads (48%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.76); catalogued as COSV63037186; called by muse, mutect2, varscan2
- SLC7A3 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 395/395 reads (100%) | SIFT tolerated (0.43); PolyPhen benign (0.171); catalogued as rs776425784, COSV53227212; called by muse, mutect2, varscan2
- SMAD6 | c.536T>G p.L179R | Missense Mutation (SNP) | VAF 331/660 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1278620954; called by muse, mutect2, varscan2
- SVEP1 | c.8438G>T p.R2813I | Missense Mutation (SNP) | VAF 256/562 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.426); catalogued as rs558094894, COSV99929893; called by muse, mutect2, varscan2
- TAF11L12 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 196/431 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs755127897; called by muse, mutect2, varscan2
- TCIRG1 | c.1592A>C p.N531T | Missense Mutation (SNP) | VAF 172/517 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1473426639; called by muse, mutect2, varscan2
- TMEM247 | c.575A>T p.E192V | Missense Mutation (SNP) | VAF 266/579 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71363764; called by muse, mutect2, varscan2
- TTC29 | c.1303G>T p.G435C | Missense Mutation (SNP) | VAF 96/239 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV57271323; called by muse, mutect2, varscan2
- TTLL3 | c.2072G>A p.R691Q | Missense Mutation (SNP) | VAF 257/568 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs770320325; called by muse, mutect2
- TTN | c.25489G>A p.D8497N (on ENST00000591111; = p.D7570N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 232/458 reads (51%) | PolyPhen probably damaging (0.926); catalogued as rs1035364658, COSV60349639; called by muse, mutect2, varscan2
- USH2A | c.15581G>A p.R5194H | Missense Mutation (SNP) | VAF 199/418 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs727505155, COSV52065509; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ZC3H12A | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 248/489 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1035304408; called by muse, mutect2, varscan2
- ZNF536 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 350/708 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs764827458; called by muse, varscan2
- ZNF787 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 253/561 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV54419851; called by muse, mutect2, varscan2
- ZSCAN1 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 108/239 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs557413199, COSV56608327; called by muse, mutect2, varscan2
- ABCA2 | c.7169A>C p.N2390T (on ENST00000614293; = p.N2360T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 188/363 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ACP7 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 350/693 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- ADAMTS16 | c.997G>T p.G333* | Nonsense Mutation (SNP) | VAF 57/122 reads (47%) | called by muse, mutect2, varscan2
- ADAMTS8 | c.1415G>A p.C472Y | Missense Mutation (SNP) | VAF 362/992 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP11 | c.4825C>T p.Q1609* | Nonsense Mutation (SNP) | VAF 204/436 reads (47%) | called by muse, mutect2, varscan2
- ARID4B | c.2573G>C p.S858T | Missense Mutation (SNP) | VAF 126/287 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- BRIP1 | c.1570C>G p.Q524E | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- C11orf68 | c.662_669del p.L221Hfs*4 (on ENST00000530188; = p.L262Hfs*4 on NM_031450.4) | Frame Shift Del (DEL) | VAF 98/851 reads (12%) | called by mutect2, pindel, varscan2
- CAD | c.4184T>G p.L1395R | Missense Mutation (SNP) | VAF 228/444 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CCDC105 | c.142C>A p.Q48K | Missense Mutation (SNP) | VAF 281/608 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCDC136 | c.783G>A p.R261= | Splice Region (SNP) | VAF 143/307 reads (47%) | called by muse, mutect2, varscan2
- CDC25A | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CFAP43 | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 40/610 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.345); called by muse, mutect2
- CFAP61 | c.1595T>A p.I532N | Missense Mutation (SNP) | VAF 123/439 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- CFAP92 | c.2398G>A p.A800T | Missense Mutation (SNP) | VAF 289/585 reads (49%) | SIFT tolerated (0.34); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CHD5 | c.2297G>T p.R766L | Missense Mutation (SNP) | VAF 333/640 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CILP2 | c.1508C>A p.T503N | Missense Mutation (SNP) | VAF 308/634 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNOT1 | c.4183C>T p.Q1395* | Nonsense Mutation (SNP) | VAF 52/528 reads (10%) | called by muse, mutect2
- CRNN | c.1355T>A p.I452N | Missense Mutation (SNP) | VAF 279/868 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- DDX4 | c.778G>C p.A260P | Missense Mutation (SNP) | VAF 193/421 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ELP1 | c.3262_3285+17del p.X1088_splice | Splice Site (DEL) | VAF 42/192 reads (22%) | called by mutect2, pindel, varscan2
- ENAM | c.3230G>T p.G1077V | Missense Mutation (SNP) | VAF 242/523 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERBB3 | c.2653T>G p.F885V | Missense Mutation (SNP) | VAF 211/409 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERVMER34-1 | c.905G>C p.G302A | Missense Mutation (SNP) | VAF 241/531 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- ETAA1 | c.1046C>A p.T349K | Missense Mutation (SNP) | VAF 72/182 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- GMIP | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 364/713 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGA4 | c.412del p.Q138Sfs*2 | Frame Shift Del (DEL) | VAF 144/417 reads (35%) | called by mutect2, pindel, varscan2
- GPR107 | c.1480_1481del p.F494Qfs*15 (on ENST00000372406 / NM_001136557.2; = p.F446Qfs*15 on NM_020960.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 47/138 reads (34%) | called by mutect2, pindel, varscan2
- GTF3C2 | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 180/368 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HCRTR1 | c.175G>T p.V59L | Missense Mutation (SNP) | VAF 31/467 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- HSDL2 | c.515A>C p.K172T | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTT | c.546T>G p.S182R | Missense Mutation (SNP) | VAF 229/528 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IFI44 | c.604T>A p.F202I | Missense Mutation (SNP) | VAF 182/395 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IL1A | c.259A>G p.S87G | Missense Mutation (SNP) | VAF 284/560 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- INSYN2B | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 232/449 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- IQCN | c.1205A>G p.K402R | Missense Mutation (SNP) | VAF 301/664 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- IRX1 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 130/262 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- KDM5C | c.4402G>C p.E1468Q | Missense Mutation (SNP) | VAF 306/306 reads (100%) | SIFT tolerated (0.41); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LEFTY2 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 371/792 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- LIFR | c.2438C>G p.A813G | Missense Mutation (SNP) | VAF 262/543 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAPK8IP1 | c.1396A>G p.S466G | Missense Mutation (SNP) | VAF 145/304 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MTCL1 | c.2053A>G p.S685G (on ENST00000306329 / NM_001378206.1; = p.S325G on NM_015210.4) | Missense Mutation (SNP) | VAF 285/914 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTTP | c.1927C>A p.L643I | Missense Mutation (SNP) | VAF 167/390 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- MYO15A | c.5971A>G p.S1991G | Missense Mutation (SNP) | VAF 295/604 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MYO18B | c.1983G>C p.W661C | Missense Mutation (SNP) | VAF 223/531 reads (42%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAV2 | c.4732C>A p.Q1578K (on ENST00000396087 / NM_001244963.2; = p.Q1555K on NM_145117.5) | Missense Mutation (SNP) | VAF 197/399 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- NFAT5 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 207/468 reads (44%) | called by muse, mutect2, varscan2
- OR13C4 | c.644T>G p.F215C | Missense Mutation (SNP) | VAF 131/322 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR13F1 | c.11C>A p.A4E | Missense Mutation (SNP) | VAF 93/212 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2J3 | c.799T>G p.S267A | Missense Mutation (SNP) | VAF 162/356 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- OR56A4 | c.161C>A p.A54E | Missense Mutation (SNP) | VAF 200/446 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OR8K3 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 196/433 reads (45%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- OTOG | c.8036A>C p.K2679T | Missense Mutation (SNP) | VAF 261/559 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- PCDH10 | c.2066G>T p.G689V | Missense Mutation (SNP) | VAF 342/657 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PCDHGB2 | c.748A>G p.T250A | Missense Mutation (SNP) | VAF 246/516 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PDE6C | c.1661A>C p.K554T | Missense Mutation (SNP) | VAF 174/360 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PDZRN4 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKD1L3 | c.4207C>A p.H1403N | Missense Mutation (SNP) | VAF 256/544 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PPEF2 | c.1239A>C p.K413N | Missense Mutation (SNP) | VAF 277/560 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- PSIP1 | c.1088T>G p.L363R | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTCHD4 | c.872A>G p.N291S | Missense Mutation (SNP) | VAF 200/419 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- PTGIS | c.285C>G p.D95E | Missense Mutation (SNP) | VAF 253/776 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRZ1 | c.2951T>C p.L984P | Missense Mutation (SNP) | VAF 302/618 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RAB32 | c.444C>A p.N148K | Missense Mutation (SNP) | VAF 220/449 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RBM15B | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 195/378 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- RCBTB1 | c.626G>C p.G209A | Missense Mutation (SNP) | VAF 176/359 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- REV1 | c.2859A>C p.Q953H | Missense Mutation (SNP) | VAF 214/471 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RGN | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 196/196 reads (100%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- RHBDD3 | c.1075T>G p.L359V | Missense Mutation (SNP) | VAF 409/851 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RNF138 | c.473A>C p.K158T | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT tolerated (0.82); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RPS6KA3 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 31/31 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- RTL1 | c.678C>A p.S226R | Missense Mutation (SNP) | VAF 195/408 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- RXYLT1 | c.439G>C p.G147R | Missense Mutation (SNP) | VAF 91/195 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCRT1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB13 | c.263A>C p.K88T | Missense Mutation (SNP) | VAF 80/172 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SKIV2L | c.1967T>C p.V656A | Missense Mutation (SNP) | VAF 229/454 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- SLC25A4 | c.221A>C p.N74T | Missense Mutation (SNP) | VAF 193/425 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- SLC38A3 | c.820T>G p.F274V | Missense Mutation (SNP) | VAF 259/562 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLCO1B3 | c.895C>A p.L299M | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.19); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- SRRM4 | c.1057A>C p.S353R | Missense Mutation (SNP) | VAF 149/318 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- STKLD1 | c.372G>T p.K124N | Missense Mutation (SNP) | VAF 173/410 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SVEP1 | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 178/378 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYCP1 | c.906G>C p.K302N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SYN3 | c.336G>T p.K112N | Missense Mutation (SNP) | VAF 139/288 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- TAS2R14 | c.404T>G p.L135R | Missense Mutation (SNP) | VAF 248/500 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TECTA | c.5632A>G p.S1878G | Missense Mutation (SNP) | VAF 198/548 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TEX13C | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 242/242 reads (100%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TEX15 | c.3268T>C p.S1090P (on ENST00000256246; = p.S1473P on NM_001350162.2) | Missense Mutation (SNP) | VAF 90/166 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- TFAP2A | c.421G>A p.A141T (on ENST00000482890; = p.A133T on NM_001032280.3) | Missense Mutation (SNP) | VAF 223/502 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TPM2 | c.267C>G p.N89K | Missense Mutation (SNP) | VAF 261/595 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- TRIB1 | c.726dup p.H243Tfs*10 | Frame Shift Ins (INS) | VAF 491/1203 reads (41%) | called by mutect2, pindel, varscan2
- TRIM5 | c.1292_1293del p.V431Dfs*5 | Frame Shift Del (DEL) | VAF 95/310 reads (31%) | called by pindel, varscan2
- TTC29 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 95/236 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- USP35 | c.583G>A p.V195M | Missense Mutation (SNP) | VAF 381/1183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- USP35 | c.1271A>G p.E424G | Missense Mutation (SNP) | VAF 277/847 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- WDFY3 | c.5916C>G p.D1972E | Missense Mutation (SNP) | VAF 204/427 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ZDHHC1 | c.896A>T p.E299V | Missense Mutation (SNP) | VAF 224/434 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.193); called by mutect2, varscan2
- ZFHX3 | c.3502G>T p.E1168* | Nonsense Mutation (SNP) | VAF 231/487 reads (47%) | called by muse, mutect2, varscan2
- ZGRF1 | c.5691G>A p.M1897I | Missense Mutation (SNP) | VAF 94/281 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF426 | c.325+1G>A p.X109_splice | Splice Site (SNP) | VAF 100/230 reads (43%) | called by muse, mutect2, varscan2
- ZNF614 | c.1559_1572delinsCAAT p.F520Sfs*75 | Frame Shift Del (DEL) | VAF 112/273 reads (41%) | called by pindel, varscan2*
- ZNF692 | c.921G>C p.W307C | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZSWIM9 | c.86A>T p.E29V | Missense Mutation (SNP) | VAF 321/668 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ADGB | c.3606T>C p.Y1202= | Silent (SNP) | VAF 153/330 reads (46%) | catalogued as COSV62230399; called by muse, mutect2, varscan2
- AHNAK2 | c.10911G>A p.K3637= | Silent (SNP) | VAF 210/507 reads (41%) | catalogued as COSV100316542; called by muse, mutect2, varscan2
- ANKFY1 | c.2886C>T p.G962= (on ENST00000341657 / NM_001330063.2; = p.G963= on NM_016376.5) | Silent (SNP) | VAF 189/405 reads (47%) | catalogued as rs746572099, COSV58918612; called by muse, mutect2, varscan2
- AREL1 | c.459C>T p.P153= | Silent (SNP) | VAF 169/344 reads (49%) | called by muse, mutect2, varscan2
- ATF5 | c.109C>T p.L37= | Silent (SNP) | VAF 458/924 reads (50%) | catalogued as COSV61312165, COSV61312481; called by muse, mutect2, varscan2
- CACNG8 | c.642C>T p.I214= | Silent (SNP) | VAF 369/754 reads (49%) | called by muse, mutect2, varscan2
- CHI3L2 | c.546G>A p.A182= | Silent (SNP) | VAF 163/365 reads (45%) | catalogued as rs143811682; called by muse, mutect2, varscan2
- CLEC9A | c.489C>T p.S163= | Silent (SNP) | VAF 137/285 reads (48%) | called by muse, mutect2, varscan2
- COG7 | c.345G>A p.K115= | Silent (SNP) | VAF 169/169 reads (100%) | called by muse, mutect2, varscan2
- CUL7 | c.2181A>G p.E727= | Silent (SNP) | VAF 129/289 reads (45%) | called by muse, mutect2, varscan2
- E2F3 | c.132C>T p.F44= | Silent (SNP) | VAF 346/706 reads (49%) | catalogued as rs746277803, COSV60895863, COSV60897568, COSV60900585; called by mutect2, varscan2
- EPPK1 | c.2985G>A p.P995= | Silent (SNP) | VAF 263/1397 reads (19%) | catalogued as rs372393547; called by muse, mutect2, varscan2
- FAM135B | c.735C>T p.C245= | Silent (SNP) | VAF 435/916 reads (47%) | called by muse, mutect2, varscan2
- FLG | c.1960A>C p.R654= | Silent (SNP) | VAF 289/981 reads (29%) | catalogued as COSV64243164; called by muse, mutect2, varscan2
- FRY | c.8682C>T p.S2894= | Silent (SNP) | VAF 252/529 reads (48%) | catalogued as rs764560797, COSV66511383; called by muse, mutect2, varscan2
- GGT5 | c.1488C>A p.I496= | Silent (SNP) | VAF 216/450 reads (48%) | called by muse, mutect2, varscan2
- HACD4 | c.159T>A p.T53= | Silent (SNP) | VAF 154/308 reads (50%) | called by muse, mutect2, varscan2
- HAUS5 | c.306G>A p.E102= | Silent (SNP) | VAF 177/409 reads (43%) | called by muse, mutect2, varscan2
- KRTAP2-3 | c.99C>T p.P33= | Silent (SNP) | VAF 178/621 reads (29%) | catalogued as rs1462891070; called by muse, mutect2, varscan2
- MED13L | c.1206A>G p.E402= | Silent (SNP) | VAF 183/349 reads (52%) | called by muse, mutect2, varscan2
- MROH6 | c.105C>G p.P35= | Silent (SNP) | VAF 814/1649 reads (49%) | called by muse, mutect2, varscan2
- MYH8 | c.4992C>G p.L1664= | Silent (SNP) | VAF 45/404 reads (11%) | called by muse, mutect2, varscan2
- NEUROG2 | c.612C>T p.S204= | Silent (SNP) | VAF 394/777 reads (51%) | catalogued as rs138686431; called by muse, mutect2, varscan2
- NT5DC2 | c.1338C>T p.G446= | Silent (SNP) | VAF 256/587 reads (44%) | catalogued as rs200027616; called by muse, mutect2, varscan2
- OR4A16 | c.741C>T p.L247= | Silent (SNP) | VAF 172/372 reads (46%) | catalogued as rs1346457574, COSV100125249, COSV59043426, COSV59045211; called by muse, mutect2, varscan2
- OR5T1 | c.522T>C p.A174= | Silent (SNP) | VAF 290/576 reads (50%) | catalogued as rs896924568; called by muse, mutect2, varscan2
- OR9I1 | c.432G>A p.L144= | Silent (SNP) | VAF 251/499 reads (50%) | called by muse, mutect2, varscan2
- OTOG | c.6858C>T p.S2286= | Silent (SNP) | VAF 249/559 reads (45%) | called by muse, mutect2, varscan2
- PAX1 | c.222C>T p.A74= | Silent (SNP) | VAF 240/699 reads (34%) | called by muse, mutect2, varscan2
- PI16 | c.468C>T p.T156= | Silent (SNP) | VAF 169/340 reads (50%) | called by muse, mutect2, varscan2
- PRKCZ | c.723C>A p.I241= | Silent (SNP) | VAF 209/411 reads (51%) | called by muse, mutect2, varscan2
- RABL6 | c.1305C>T p.N435= | Silent (SNP) | VAF 243/516 reads (47%) | catalogued as rs776544151; called by muse, mutect2, varscan2
- RP1L1 | c.1182C>A p.V394= | Silent (SNP) | VAF 283/582 reads (49%) | called by muse, mutect2, varscan2
- SDHAF3 | c.6G>C p.P2= | Silent (SNP) | VAF 121/286 reads (42%) | catalogued as rs566561181; called by muse, mutect2, varscan2
- SRRM2 | c.1200T>C p.T400= | Silent (SNP) | VAF 294/609 reads (48%) | catalogued as rs924219840; called by muse, mutect2, varscan2
- TLX1 | c.33G>T p.P11= | Silent (SNP) | VAF 313/616 reads (51%) | called by muse, mutect2, varscan2
- ZCCHC2 | c.2277T>C p.S759= | Silent (SNP) | VAF 221/454 reads (49%) | called by muse, mutect2, varscan2
- ZNF425 | c.930C>G p.A310= | Silent (SNP) | VAF 316/963 reads (33%) | called by muse, mutect2, varscan2
- ZNF735 | c.1206T>C p.I402= | Silent (SNP) | VAF 57/129 reads (44%) | called by muse, mutect2, varscan2
- BIRC8 | n.1712T>C | RNA (SNP) | VAF 158/364 reads (43%) | called by muse, varscan2
- BPI | c.613-677dup | Intron (INS) | VAF 177/644 reads (27%) | called by mutect2, pindel, varscan2
- FLCN | c.871+123A>G | Intron (SNP) | VAF 258/519 reads (50%) | called by muse, mutect2, varscan2
- KTN1 | c.2173-2575T>G | Intron (SNP) | VAF 141/267 reads (53%) | called by muse, mutect2, varscan2
- PDGFC | c.-434G>A | 5'UTR (SNP) | VAF 162/372 reads (44%) | called by muse, mutect2, varscan2
- STXBP6 | c.452-21C>T | Intron (SNP) | VAF 138/563 reads (25%) | called by muse, mutect2, varscan2
- YME1L1 | c.339+52T>A | Intron (SNP) | VAF 280/550 reads (51%) | called by muse, mutect2, varscan2
